Gene-level copy-number profile of tumor specimen TCGA-L5-A4OP-01A from TCGA case TCGA-L5-A4OP, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 68.0 years (24,829 days).
Specimen TCGA-L5-A4OP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.66d6122e-bdc9-4085-88ae-a0fe5e1d8bd1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-L5-A4OP-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/00b4b8c8-12a1-413f-8603-1ee64065a5b4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 19,669; copy number 2: 35,111; copy number 3: 4,697; copy number 4: 251; copy number 5: 14; copy number 6: 60; copy number 7: 2; copy number 11: 2; copy number 12: 6; copy number 13: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-L5-A4OP-01A-11D-A25X-01): tumor purity 0.72, ploidy 1.81, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 87 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:176,857,302–178,726,285, 23 genes, copy number 5–13 (within-gene range 3–13): ASTN1, MIR488, BRINP2, LINC01645, AL136114.1, LINC01741, SEC16B, CRYZL2P-SEC16B, CRYZL2P, AL359075.1, RASAL2-AS1, RASAL2, AL160281.1, AL365357.1, CLEC20A, Metazoa_SRP, AL513013.1, TEX35, C1orf220, RNA5SP69, AL137796.1, MIR4424, AL449106.1.
- chr1:178,746,683–178,753,772, 2 genes, copy number 13: PTPN2P1, SNORA63.
- chr3:157,976,561–158,545,730, 5 genes, copy number 6 (within-gene range 3–6): AC079943.1, SHOX2, RSRC1, AC074276.1, AC074276.2.
- chr3:169,966,635–169,998,373, 2 genes, copy number 7: SEC62, SEC62-AS1.
- chr6:42,963,865–44,089,288, 55 genes, copy number 6 (within-gene range 3–6): PEX6, PPP2R5D, MEA1, KLHDC3, RRP36, AL136304.1, RN7SL403P, CUL7, KLC4, AL355385.2, MRPL2, AL355385.1, PTK7, SRF, CUL9, AL133375.1, DNPH1, TTBK1, SLC22A7, CRIP3, ZNF318, RPL12P47, AL583834.1, RPS2P28, AL590383.1, AL359813.1, AL359813.2, ABCC10, MIR6780B, DLK2, RNU6-1113P, TJAP1, LRRC73, POLR1C, YIPF3, AL355802.3, XPO5, AL355802.1, AL355802.2, POLH, POLH-AS1, GTPBP2, MAD2L1BP, RSPH9, MRPS18A, AL136131.1, AL136131.2, VEGFA, AL136131.3, AL157371.2, LINC02537, AL157371.1, AL109615.3, C6orf223, AL109615.2.

Autosomal genes at a single copy (total copy number 1): 19,669. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
